CCDI case PBBRPZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/5b4bfa01-6b5a-46c7-b5b0-ab81023c6b8e

Demographics
Sex at birth: female; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Medullary carcinoma, NOS: ICD-O-3 morphology code: 8510/3; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 15.1 years (5,522 days).

Biospecimens (2 samples)
- Sample 0DG5A9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DG5AF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
